Somatic mutation profile of tumor specimen 0DSF02 from CCDI case PBCHUX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.0 years (378 days).
Specimen 0DSF02: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2883fb4-55de-48e6-b7d9-7f4b9f4e9587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEYW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8574ac90-3b11-46fa-8d8a-076cbc768ae6

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1321C>T p.R441W (on ENST00000281708 / NM_001349798.2; = p.R361W on NM_018315.5) | Missense Mutation (SNP) | VAF 318/369 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55897212, COSV55936558; called by muse, mutect2, varscan2
- HPS6 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 280/665 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs780449497, COSV54626280; called by muse, mutect2, varscan2
- INSM1 | c.263T>A p.F88Y | Missense Mutation (SNP) | VAF 40/651 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2
- INSM1 | c.264C>A p.F88L | Missense Mutation (SNP) | VAF 40/657 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2
- KMT2D | c.10534G>T p.E3512* | Nonsense Mutation (SNP) | VAF 181/574 reads (32%) | called by muse, mutect2, varscan2
- TRNP1 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 324/630 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- HCN3 | c.1149C>T p.R383= | Silent (SNP) | VAF 276/860 reads (32%) | called by muse, mutect2, varscan2
- HPS6 | c.1818C>A p.R606= | Silent (SNP) | VAF 279/660 reads (42%) | called by muse, mutect2, varscan2
